Gene-level copy-number profile of tumor specimen TCGA-FG-8182-01A from TCGA case TCGA-FG-8182, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Oligodendroglioma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 35.5 years (12,972 days).
Specimen TCGA-FG-8182-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LGG.db73c1c1-1ba2-4494-986b-e2b674911252.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-FG-8182-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/7a419ade-fb5b-421d-9465-d199c2f0a408

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 3,846; copy number 2: 53,515; copy number 3: 1,149; copy number 4: 487; copy number 5: 113; copy number 6: 709.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-FG-8182-01A-11D-2252-01): tumor purity 0.19, ploidy 2.11, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 822 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:128,862,042–128,910,719, 1 gene, copy number 6 (within-gene range 2–6): KCP.
- chr7:128,912,732–159,233,377, 708 genes, copy number 6 (broad region; genes not listed).
- chr12:19,941,521–26,833,194, 105 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr13:73,686,089–73,995,056, 1 gene, copy number 5 (within-gene range 2–5): KLF12.
- chr13:73,844,683–74,444,735, 7 genes, copy number 5 (within-gene range 2–5): AL159972.1, LINC00402, AL353660.1, RNY1P5, RPL21P108, AL355390.1, LINC00381.

Autosomal genes at a single copy (total copy number 1): 1,466. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
